Somatic mutation profile of tumor specimen MP2PRT-PAVWEV-TMP1-A (aliquot MP2PRT-PAVWEV-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVWEV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,245 days).
Specimen MP2PRT-PAVWEV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdb74ba9-180b-4deb-8a19-6ffe03dce593.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWEV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWEV-NM1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c034b6cd-c286-48c6-85f6-05b7ce930c4e

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 111/138 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880471; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.371C>G p.S124W | Missense Mutation (SNP) | VAF 208/510 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV67125673, COSV67136081, COSV67136513; called by muse, mutect2, varscan2
- CEACAM3 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 25/600 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55760630, COSV99705140; called by muse, mutect2
- FMOD | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 31/575 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs374392393; called by muse, mutect2
- GABRA1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 127/326 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV50098481, COSV99195673; called by muse, mutect2, varscan2
- GLIS1 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 306/740 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.727); catalogued as rs562032170; called by muse, mutect2, varscan2
- PRLHR | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 313/688 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1443595151, COSV53304727; called by muse, mutect2, varscan2
- PTCH1 | c.2839G>C p.E947Q | Missense Mutation (SNP) | VAF 83/507 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as rs768039033, CM115300, COSV59461003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELCH | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 133/611 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.147); catalogued as rs781566024, COSV56884190, COSV99902004; called by muse, mutect2, varscan2
- RGPD3 | c.3014C>G p.S1005* | Nonsense Mutation (SNP) | VAF 223/589 reads (38%) | catalogued as rs1178102902; called by muse, mutect2, varscan2
- RIMBP2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 203/850 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs201451845; called by muse, mutect2, varscan2
- SLC25A13 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 166/399 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV55705714; called by muse, mutect2, varscan2
- CCHCR1 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 101/443 reads (23%) | called by muse, mutect2, varscan2
- FOXL2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 28/986 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- GUCY1B1 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRT20 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 169/790 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- LGSN | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 134/350 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCF2L2 | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 18/533 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.15170C>G p.S5057C | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- OGFOD1 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PDCD2L | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POGZ | c.1281G>C p.E427D | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RBM27 | c.1647C>A p.S549R | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- SELENBP1 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 154/524 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SYCP2 | c.3608G>C p.S1203T | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMIGD2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 69/404 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TP63 | c.548A>C p.Q183P | Missense Mutation (SNP) | VAF 254/581 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV4 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 84/544 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TXNDC11 | c.1993C>G p.Q665E (on ENST00000356957 / NM_001303447.2; = p.Q638E on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/277 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZMYM2 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 92/205 reads (45%) | called by muse, mutect2, varscan2
- ZNF12 | c.1452G>C p.Q484H (on ENST00000405858 / NM_016265.4; = p.Q446H on NM_006956.3) | Missense Mutation (SNP) | VAF 19/633 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ZNF787 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 30/1064 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.224); called by muse, mutect2
- CELF3 | c.456C>T p.I152= | Silent (SNP) | VAF 28/935 reads (3%) | called by muse, mutect2
- ETAA1 | c.1458T>C p.N486= | Silent (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- FN1 | c.1584C>T p.N528= | Silent (SNP) | VAF 67/362 reads (19%) | catalogued as rs528350304, COSV60566264; called by muse, mutect2, varscan2
- FOXL2 | c.258G>C p.A86= | Silent (SNP) | VAF 30/896 reads (3%) | catalogued as COSV100374601; called by muse, mutect2
- FUOM | c.24C>A p.P8= | Silent (SNP) | VAF 282/629 reads (45%) | called by muse, mutect2, varscan2
- KIF9 | c.2001G>A p.K667= (on ENST00000265529 / NM_001377474.1; = p.K602= on NM_022342.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/705 reads (3%) | called by muse, mutect2
- LAS1L | c.384G>A p.E128= | Silent (SNP) | VAF 180/206 reads (87%) | catalogued as rs1423475744; called by muse, mutect2, varscan2
- METTL27 | c.399C>T p.D133= | Silent (SNP) | VAF 199/478 reads (42%) | catalogued as rs200039404; called by muse, varscan2
- MYH1 | c.3120A>C p.G1040= | Silent (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- PNMT | c.687G>C p.L229= | Silent (SNP) | VAF 30/802 reads (4%) | called by muse, mutect2
- TOX | c.204C>T p.F68= | Silent (SNP) | VAF 84/397 reads (21%) | called by muse, mutect2, varscan2
- KCNAB2 | c.119+9847C>T | Intron (SNP) | VAF 187/651 reads (29%) | catalogued as rs1217388977, COSV51238666; called by muse, mutect2, varscan2
